Somatic mutation profile of tumor specimen TCGA-XM-A8R8-01A (aliquot TCGA-XM-A8R8-01A-11D-A423-09) from TCGA case TCGA-XM-A8R8, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 67.1 years (24,508 days).
Specimen TCGA-XM-A8R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26806b24-0493-4cfb-becd-f7b1311c9ea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8R8-10B (Blood Derived Normal), aliquot TCGA-XM-A8R8-10B-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e0dc25b-e267-4e10-aea4-7fbbe4aee0e7

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAB1 | c.2687G>T p.S896I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MYOD1 | c.441G>T p.V147= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
